Somatic mutation profile of tumor specimen TCGA-AG-3892-01A (aliquot TCGA-AG-3892-01A-01W-1073-09) from TCGA case TCGA-AG-3892, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 57.2 years (20,880 days).
Specimen TCGA-AG-3892-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9850ff0a-02f5-4705-a652-bc6385752b04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3892-10A (Blood Derived Normal), aliquot TCGA-AG-3892-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dc91101-0bbc-4760-bea8-5dcd2cb1bcbc

The open-access MAF lists 2,757 somatic variants for this specimen: 2,280 protein-altering or splice-affecting, 413 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,904, Silent 413, Nonsense Mutation 322, Splice Site 28, RNA 23, Intron 20, Splice Region 12, 3'UTR 10, Frame Shift Del 5, 5'UTR 5, Frame Shift Ins 4, Nonstop Mutation 4.

Variants (750 of 2,757; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 77/175 reads (44%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 46/208 reads (22%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.1942G>T p.E648* | Nonsense Mutation (SNP) | VAF 30/180 reads (17%) | catalogued as rs971882211, CM141595, COSV55735390; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as rs1393544920, COSV100483393, COSV58591239; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CYBB | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 26/170 reads (15%) | catalogued as rs886041192, CM960436, COSV66085069; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DHDDS | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.019); catalogued as rs1229969030, COSV52575269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.8944C>T p.R2982* | Nonsense Mutation (SNP) | VAF 14/133 reads (11%) | catalogued as rs128625229, CM920238, COSV100625881; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 37/171 reads (22%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs200698994; called by muse, mutect2, varscan2
- FGFR2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 23/152 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs747502397, COSV60645207, COSV60646793; ClinVar: uncertain significance; called by muse, mutect2
- MSH6 | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 44/206 reads (21%) | catalogued as rs1553333707, CM1412053, COSV52274101; ClinVar: pathogenic; called by muse, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 45/208 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OTX2 | c.265C>T p.R89* (on ENST00000408990 / NM_172337.3; = p.R97* on NM_021728.4) | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as rs104894464, CM051593, CM104945, COSV59766659; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RFX6 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445567359, COSV60586495, COSV60587831; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520009, COSV68944533, COSV68945324; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs570351376, COSV52628354; called by muse, mutect2, varscan2
- AASDHPPT | c.626T>C p.I209T | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV53789463; called by muse, mutect2, varscan2
- ABCA10 | c.2206C>A p.L736I | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV52221612; called by muse, mutect2, varscan2
- ABCA12 | c.2285T>G p.L762* (on ENST00000272895 / NM_173076.3; = p.L444* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 21/109 reads (19%) | catalogued as CM153356, COSV55964590; called by muse, mutect2, varscan2
- ABCA12 | c.1211G>A p.R404Q (on ENST00000272895 / NM_173076.3; = p.R86Q on NM_015657.3) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs752328328, COSV55961290, COSV99789386; called by muse, mutect2, varscan2
- ABCA13 | c.5881A>C p.N1961H | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV70027176; called by muse, mutect2, varscan2
- ABCA9 | c.3800G>A p.R1267K | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV60626993; called by muse, mutect2, varscan2
- ABCB1 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 84/551 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55954869; called by muse, mutect2, varscan2
- ABCB1 | c.826A>T p.R276W | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55952376, COSV99712463; called by muse, mutect2
- ABCB4 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55937335; called by muse, mutect2, varscan2
- ABCC11 | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 39/213 reads (18%) | catalogued as COSV62324111; called by muse, mutect2, varscan2
- ABCC11 | c.752C>A p.S251Y | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1382483134, COSV100750621; called by muse, mutect2
- ABCC2 | c.3053C>A p.S1018Y | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV64986928; called by muse, mutect2, varscan2
- ABCC8 | c.3540C>A p.Y1180* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV56852727; called by muse, mutect2, varscan2
- ABCD2 | c.1417G>T p.D473Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV58052676; called by muse, varscan2
- ABCG2 | c.1527G>T p.M509I | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV52947037; called by muse, mutect2, varscan2
- ABCG2 | c.1356G>T p.K452N | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV52947046; called by muse, mutect2, varscan2
- ABI3 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99865359; called by muse, varscan2
- AC006059.2 | c.874A>C p.I292L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as COSV59607884; called by muse, mutect2, varscan2
- AC098582.1 | c.2111T>C p.V704A | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52021686; called by muse, mutect2, varscan2
- AC127029.3 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs140787052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC134980.2 | c.712T>C p.S238P | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754080672, COSV100171525; called by muse, mutect2, varscan2
- ACAD9 | c.668T>G p.F223C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100459022; called by muse, mutect2
- ACADM | c.143T>G p.F48C | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63720642; called by muse, mutect2, varscan2
- ACBD6 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs777457819, COSV62571410, COSV62574403; called by muse, mutect2, varscan2
- ACCSL | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV66581644; called by mutect2, varscan2
- ACKR2 | c.750A>C p.K250N | Missense Mutation (SNP) | VAF 53/396 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); catalogued as COSV56178490; called by muse, mutect2, varscan2
- ACOT6 | c.357C>A p.F119L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV66969232; called by muse, mutect2, varscan2
- ACOT9 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV60538191; called by muse, mutect2, varscan2
- ACOX3 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.772); catalogued as COSV62712554, COSV62713252; called by muse, mutect2, varscan2
- ACOX3 | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100711864; called by muse, mutect2
- ACR | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV53361322; called by muse, mutect2, varscan2
- ACSBG2 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV53125808; called by muse, varscan2
- ACSL3 | c.658A>C p.K220Q | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100657893; called by muse, mutect2
- ACVR2B | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100754186; called by muse, mutect2
- ACYP1 | c.39A>C p.E13D | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53135311; called by muse, mutect2, varscan2
- ADAD1 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 19/125 reads (15%) | catalogued as COSV56643345, COSV56644581; called by muse, mutect2, varscan2
- ADAM21 | c.484A>C p.N162H | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV50797475; called by muse, mutect2, varscan2
- ADAM23 | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV100007065; called by muse, mutect2
- ADAMTS12 | c.4160G>A p.R1387H | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745489312, COSV61254566, COSV61256573, COSV61285243; called by muse, mutect2, varscan2
- ADAMTS18 | c.2802-1G>T p.X934_splice | Splice Site (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99271690; called by muse, mutect2, varscan2
- ADAMTS18 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs746386082, COSV51417926; called by muse, mutect2, varscan2
- ADAMTS18 | c.1523A>C p.D508A | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV51417931; called by muse, mutect2, varscan2
- ADAMTS3 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.143); catalogued as rs1444087701, COSV54394986; called by muse, varscan2
- ADAMTS5 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.835); catalogued as rs546124249, COSV53175804; called by muse, mutect2, varscan2
- ADAMTS9 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs766944266, COSV55777384; called by muse, varscan2
- ADAMTSL2 | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100618940; called by muse, mutect2
- ADAMTSL3 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs751167134, COSV54439652; called by muse, mutect2, varscan2
- ADCK1 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV99451232; called by muse, mutect2, varscan2
- ADCK1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372281167, COSV53082469; called by muse, mutect2
- ADCY10 | c.3111C>A p.F1037L | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV63238491; called by muse, mutect2, varscan2
- ADCY10 | c.646A>G p.N216D | Missense Mutation (SNP) | VAF 102/479 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV63241920; called by muse, mutect2, varscan2
- ADCY2 | c.211-2A>C p.X71_splice | Splice Site (SNP) | VAF 43/195 reads (22%) | catalogued as COSV100602176; called by muse, mutect2, varscan2
- ADCY8 | c.1024T>C p.S342P | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV99651313; called by muse, mutect2
- ADGRB3 | c.379T>G p.F127V | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101000204; called by muse, mutect2
- ADGRB3 | c.1657C>A p.L553I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV101000206; called by muse, mutect2, varscan2
- ADGRF1 | c.764-1G>A p.X255_splice | Splice Site (SNP) | VAF 7/102 reads (7%) | catalogued as rs1162554604, COSV99347077; called by muse, mutect2
- ADGRF1 | c.572G>T p.R191I | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.403); catalogued as rs753292636, COSV51944555, COSV51946042; called by muse, mutect2, varscan2
- ADGRG4 | c.2642C>A p.S881Y | Missense Mutation (SNP) | VAF 242/1361 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV54960054; called by muse, mutect2, varscan2
- ADGRG4 | c.2797T>G p.F933V | Missense Mutation (SNP) | VAF 50/1359 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99794836; called by muse, mutect2
- ADGRG4 | c.3941C>T p.S1314L | Missense Mutation (SNP) | VAF 157/597 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs751562884, COSV54950446; called by muse, mutect2, varscan2
- ADGRL3 | c.1433C>A p.S478Y (on ENST00000506720 / NM_001322402.2; = p.S410Y on NM_015236.6) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV72267671, COSV72269295; called by muse, mutect2, varscan2
- ADGRV1 | c.958C>A p.L320M | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.352); catalogued as COSV101315639; called by muse, mutect2
- ADGRV1 | c.2483T>C p.V828A | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs757135353, COSV67988569; called by muse, mutect2, varscan2
- ADGRV1 | c.14404C>T p.R4802* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as rs1236715896, CM0911268, COSV67978996; called by muse, mutect2
- ADGRV1 | c.16639C>T p.R5547C | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs1446694263, COSV67987576; called by muse, mutect2, varscan2
- ADH1B | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV59297101; called by muse, mutect2, varscan2
- ADH6 | c.1023G>T p.L341F | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52956749; called by muse, mutect2, varscan2
- ADNP2 | c.753T>G p.I251M | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51540059; called by muse, mutect2, varscan2
- AFF1 | c.3092C>A p.S1031* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV57121220; called by muse, mutect2, varscan2
- AFF2 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 48/914 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV60663924; called by muse, mutect2
- AFF2 | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782465333, CM128723, COSV53995030; called by muse, mutect2, varscan2
- AFF2 | c.3805G>T p.E1269* | Nonsense Mutation (SNP) | VAF 26/348 reads (7%) | catalogued as COSV54008651, COSV99662654; called by muse, mutect2
- AFTPH | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 31/148 reads (21%) | catalogued as COSV53218714, COSV53219240; called by muse, mutect2, varscan2
- AGBL5 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs745474264, COSV59936998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGGF1 | c.954G>T p.K318N | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV57229552; called by muse, mutect2
- AGPAT5 | c.885T>G p.F295L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV53447755; called by muse, mutect2, varscan2
- AGTR2 | c.464G>T p.R155I | Missense Mutation (SNP) | VAF 120/519 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64156183; called by muse, mutect2, varscan2
- AHNAK | c.6435T>G p.D2145E | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99946304; called by muse, mutect2
- AICDA | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs1489687161, CM064963, COSV57564138; called by muse, mutect2, varscan2
- AIFM1 | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as COSV54855748; called by muse, mutect2, varscan2
- AKAP3 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 34/276 reads (12%) | catalogued as rs1467971895, COSV57413779; called by muse, mutect2, varscan2
- AKAP4 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV62074797; called by muse, mutect2, varscan2
- AKAP9 | c.254G>T p.R85I | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62350086; called by muse, mutect2, varscan2
- AKAP9 | c.10516C>A p.L3506I (on ENST00000359028; = p.L3482I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as COSV62350106; called by muse, mutect2, varscan2
- AKIRIN2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57636871; called by muse, mutect2
- AKR1C1 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV101080407; called by muse, mutect2
- AKR1C2 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 19/139 reads (14%) | catalogued as COSV66333502, COSV66334408; called by muse, mutect2, varscan2
- AKR1C4 | c.958T>G p.S320A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54123939; called by muse, mutect2, varscan2
- AKT3 | c.1212C>A p.F404L | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55621735, COSV55629831; called by muse, mutect2
- AL136295.1 | c.1095G>T p.K365N | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV55780584; called by muse, mutect2, varscan2
- AL163195.3 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.398); catalogued as COSV100250465; called by muse, mutect2, varscan2
- ALB | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs774294755, COSV55738750, COSV55739357; called by muse, mutect2, varscan2
- ALB | c.1782G>T p.E594D | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV55739365; called by muse, mutect2, varscan2
- ALG14 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs767402341, COSV64635180; called by muse, mutect2, varscan2
- ALG9 | c.1027T>G p.L343V | Missense Mutation (SNP) | VAF 35/348 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV67644669; called by muse, mutect2, varscan2
- ALMS1 | c.8077G>T p.E2693* | Nonsense Mutation (SNP) | VAF 132/700 reads (19%) | catalogued as rs1411820884, COSV52513283; called by muse, varscan2
- ALPK1 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779895727, COSV51583461; called by muse, mutect2, varscan2
- AMER1 | c.1621A>C p.N541H | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV57662703; called by muse, mutect2, varscan2
- AMER1 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 73/339 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.902); catalogued as COSV57662720; called by muse, mutect2, varscan2
- AMPD1 | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.93); catalogued as COSV62416866; called by muse, mutect2, varscan2
- AMY2B | c.692A>C p.N231T | Missense Mutation (SNP) | VAF 42/527 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV63715875; called by muse, mutect2
- ANGEL2 | c.885A>C p.K295N | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV64737575; called by muse, mutect2, varscan2
- ANK2 | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.218); catalogued as rs772853667, COSV52169808; called by muse, mutect2, varscan2
- ANK2 | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as rs1162799877, COSV52158299; called by muse, mutect2, varscan2
- ANK2 | c.6082C>T p.R2028W | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1411026310, COSV52150851; called by muse, mutect2, varscan2
- ANK3 | c.6596C>A p.T2199N | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.068); catalogued as COSV55065061, COSV55067717; called by muse, mutect2, varscan2
- ANKAR | c.309G>T p.M103I | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99854019; called by muse, varscan2
- ANKAR | c.361A>C p.S121R | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1334917028, COSV99854023; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 27/130 reads (21%) | catalogued as COSV51851070; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2164A>G p.T722A | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51851091; called by muse, mutect2, varscan2
- ANKRD1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs780993838, COSV63311064; called by muse, mutect2, varscan2
- ANKRD12 | c.2094G>T p.E698D | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV50831088; called by muse, mutect2, varscan2
- ANKRD24 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as rs537535275, COSV53672336; called by mutect2, varscan2
- ANKRD36B | c.1525G>T p.D509Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs749145841, COSV51533596; called by muse, mutect2, varscan2
- ANKRD50 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 39/179 reads (22%) | catalogued as COSV72385820; called by muse, mutect2, varscan2
- ANKRD55 | c.1246T>C p.Y416H | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.057); catalogued as COSV61947793; called by muse, mutect2, varscan2
- ANO2 | c.1144C>A p.L382I (on ENST00000356134 / NM_001278597.3; = p.L386I on NM_001278596.3) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.624); catalogued as COSV100500159, COSV59024171; called by muse, mutect2
- ANO5 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61083785, COSV61087223; called by muse, mutect2, varscan2
- ANXA13 | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.197); catalogued as COSV51624462; called by muse, mutect2, varscan2
- ANXA13 | c.578T>C p.F193S | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99146057; called by muse, mutect2
- AP002512.3 | c.559A>C p.N187H | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99687823; called by muse, mutect2
- AP3B1 | c.2734C>T p.R912* | Nonsense Mutation (SNP) | VAF 71/218 reads (33%) | catalogued as rs752519227, COSV54877147; called by muse, mutect2, varscan2
- AP3M2 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs756052697, COSV51529483; called by muse, mutect2, varscan2
- APC | c.3483T>G p.N1161K | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV57355164; called by muse, mutect2, varscan2
- APLF | c.342-1G>T p.X114_splice | Splice Site (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100376481; called by muse, mutect2, varscan2
- APLP2 | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53841780; called by muse, mutect2, varscan2
- APOB | c.9803C>T p.S3268L | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755753053, COSV51924885; called by muse, mutect2, varscan2
- APOBEC4 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as rs867527033, COSV58017983; called by muse, mutect2, varscan2
- ARAP2 | c.3679G>T p.A1227S | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV100394789, COSV58288491; called by muse, mutect2, varscan2
- ARAP2 | c.1810T>G p.F604V | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV58284983; called by muse, mutect2, varscan2
- ARAP2 | c.1056G>T p.K352N | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.102); catalogued as COSV58288508; called by muse, mutect2, varscan2
- ARAP2 | c.965-1G>T p.X322_splice | Splice Site (SNP) | VAF 21/108 reads (19%) | catalogued as COSV58282395, COSV58291435; called by muse, mutect2, varscan2
- ARFGEF1 | c.2098G>T p.E700* | Nonsense Mutation (SNP) | VAF 26/140 reads (19%) | catalogued as COSV51610855; called by muse, mutect2, varscan2
- ARGLU1 | c.692G>T p.R231I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65608292; called by muse, mutect2, varscan2
- ARHGAP11A | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760030538, COSV64380588; called by muse, mutect2, varscan2
- ARHGAP15 | c.385-1G>T p.X129_splice | Splice Site (SNP) | VAF 22/127 reads (17%) | catalogued as COSV99709319; called by muse, mutect2, varscan2
- ARHGAP19 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as rs771390013, COSV57393724; called by muse, mutect2, varscan2
- ARHGAP31 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV51790087; called by muse, mutect2, varscan2
- ARHGAP31 | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 102/401 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1400666120, COSV51795175; called by muse, mutect2, varscan2
- ARHGAP36 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.14); catalogued as rs745365369, COSV52264522; called by muse, mutect2, varscan2
- ARHGAP5 | c.3351T>G p.N1117K | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as rs779050241, COSV61536969; called by muse, mutect2, varscan2
- ARHGAP6 | c.1916A>C p.D639A | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV57298079; called by muse, mutect2, varscan2
- ARHGEF11 | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746467759, COSV59352836; called by mutect2, varscan2
- ARHGEF12 | c.4417G>A p.E1473K | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as rs1486039186, COSV100754663; called by muse, mutect2
- ARID4A | c.3680C>T p.A1227V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs763843963, COSV62164751; called by muse, mutect2, varscan2
- ARID5B | c.1015A>G p.I339V | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV54423317; called by muse, mutect2
- ARMC3 | c.302A>C p.K101T | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99957699; called by muse, mutect2
- ARMH4 | c.1669C>A p.L557M | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV50766893; called by muse, mutect2, varscan2
- ARNT2 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 23/454 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100308733; called by muse, mutect2
- ARPP21 | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs1378396699, COSV51801042; called by muse, mutect2, varscan2
- ARRDC4 | c.323T>C p.L108S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV99164329; called by muse, mutect2, varscan2
- ART3 | c.662G>T p.R221I | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs550091630, COSV61913555; called by muse, mutect2
- ART4 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV57452410; called by muse, mutect2, varscan2
- ASB7 | c.944T>G p.F315C | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.869); catalogued as COSV100234894, COSV60417325; called by muse, mutect2, varscan2
- ASH1L | c.2972C>A p.T991N | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as COSV64209821; called by muse, mutect2, varscan2
- ASIC5 | c.1112C>A p.S371Y | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV101611115; called by muse, mutect2
- ASTE1 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs750336679, COSV53909167; called by muse, mutect2, varscan2
- ASTN1 | c.3412G>A p.D1138N | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs778027121, COSV62499427; called by muse, mutect2, varscan2
- ASXL1 | c.1062C>A p.F354L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60111699; called by muse, mutect2, varscan2
- ASXL1 | c.3100A>G p.K1034E | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.841); catalogued as COSV60111707; called by muse, mutect2, varscan2
- ASXL2 | c.993C>A p.F331L | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55454364, COSV99712155; called by muse, mutect2, varscan2
- ATAD2 | c.3620A>G p.D1207G | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99784278; called by muse, mutect2
- ATAD5 | c.739A>C p.N247H | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58975990; called by muse, mutect2, varscan2
- ATE1 | c.380A>C p.D127A | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as COSV56438194; called by muse, mutect2, varscan2
- ATG2B | c.3154C>A p.L1052I | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV63422145, COSV63424081; called by muse, mutect2
- ATG4C | c.1346G>T p.R449I | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs749357381, COSV58603833, COSV58606729; called by muse, mutect2, varscan2
- ATM | c.2933C>A p.S978Y | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53781594; called by muse, mutect2, varscan2
- ATM | c.7669T>G p.L2557V | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV53752809; called by muse, mutect2, varscan2
- ATP10A | c.666C>A p.F222L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as COSV100790999, COSV63517451; called by muse, mutect2
- ATP10B | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs201710345; called by muse, mutect2, varscan2
- ATP12A | c.2136G>T p.Q712H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54518553; called by muse, mutect2, varscan2
- ATP13A4 | c.2327T>C p.I776T | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as COSV61321666; called by muse, mutect2, varscan2
- ATP13A5 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.275); catalogued as COSV60868697; called by muse, mutect2, varscan2
- ATP2A2 | c.2062G>T p.E688* | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as COSV57875702; called by muse, mutect2, varscan2
- ATP2B2 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59500050; called by muse, mutect2, varscan2
- ATP2B2 | c.257T>G p.F86C | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100659856; called by muse, mutect2
- ATP2C2 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 58/350 reads (17%) | catalogued as COSV52297669; called by muse, mutect2, varscan2
- ATP6V1B2 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 18/157 reads (11%) | catalogued as rs777139485, COSV52352683; called by muse, mutect2, varscan2
- ATP8A2 | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54960468; called by muse, mutect2, varscan2
- ATP8B1 | c.3373C>A p.L1125I | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52177288; called by muse, mutect2, varscan2
- ATP8B4 | c.1443G>T p.E481D | Missense Mutation (SNP) | VAF 42/536 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99464374; called by muse, mutect2
- ATR | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs911751877, COSV63384264; called by muse, mutect2, varscan2
- ATRX | c.6938T>C p.L2313S | Missense Mutation (SNP) | VAF 101/489 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV100970277, COSV64874125; called by muse, mutect2, varscan2
- ATRX | c.5478C>A p.F1826L | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100970118; called by muse, mutect2
- ATRX | c.3835G>T p.E1279* | Nonsense Mutation (SNP) | VAF 38/174 reads (22%) | catalogued as COSV100970278; called by muse, mutect2, varscan2
- ATRX | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 22/545 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV100970282; called by muse, mutect2
- ATXN3L | c.329G>T p.R110I | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as COSV101019339; called by muse, mutect2
- AURKAIP1 | c.502A>C p.K168Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV100408636; called by muse, mutect2, varscan2
- AUTS2 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61412662; called by muse, mutect2, varscan2
- B2M | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62564953; called by muse, mutect2, varscan2
- B2M | c.228C>A p.F76L | Missense Mutation (SNP) | VAF 22/321 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100837581; called by muse, mutect2
- B2M | c.346+2T>C p.X116_splice | Splice Site (SNP) | VAF 11/207 reads (5%) | catalogued as COSV62565080, COSV62565694; called by muse, mutect2
- BACE2 | c.512C>A p.T171N | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV100160630; called by muse, mutect2
- BAG5 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1488802882, COSV54571459; called by mutect2, varscan2
- BAG5 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV54571467; called by muse, mutect2, varscan2
- BANK1 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 27/178 reads (15%) | catalogued as COSV59845318, COSV59849860; called by muse, mutect2, varscan2
- BARD1 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758749603, COSV53613427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ1B | c.3311T>C p.V1104A | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100289635; called by muse, mutect2
- BBOX1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1379464119, COSV54191958; called by muse, mutect2, varscan2
- BCL2A1 | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 36/297 reads (12%) | catalogued as COSV51213429, COSV51213657; called by muse, varscan2
- BCL2A1 | c.347A>C p.K116T | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV51213158; called by muse, varscan2
- BCL7B | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.238); catalogued as rs782334386, COSV56270029; called by muse, mutect2, varscan2
- BCL9 | c.1026dup p.T343Hfs*34 | Frame Shift Ins (INS) | VAF 13/103 reads (13%) | catalogued as rs1553204401; called by mutect2, varscan2
- BCOR | c.4734C>A p.F1578L (on ENST00000378444 / NM_001123385.2; = p.F1544L on NM_017745.6) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60710884; called by muse, mutect2, varscan2
- BEND2 | c.1181-1G>T p.X394_splice | Splice Site (SNP) | VAF 10/212 reads (5%) | catalogued as COSV101191882; called by muse, mutect2
- BEND3 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as rs782731122, COSV64681450; called by muse, mutect2, varscan2
- BEST3 | c.1849C>A p.L617I | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.146); catalogued as rs745371418, COSV58302624; called by muse, mutect2, varscan2
- BEST3 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.101); catalogued as rs1326380921, COSV56995066; called by muse, mutect2, varscan2
- BIRC6 | c.6916G>T p.E2306* | Nonsense Mutation (SNP) | VAF 29/158 reads (18%) | catalogued as COSV70201730; called by muse, mutect2, varscan2
- BIRC6 | c.8371G>T p.E2791* | Nonsense Mutation (SNP) | VAF 9/190 reads (5%) | catalogued as COSV70207841; called by muse, mutect2
- BIRC6 | c.9967G>A p.V3323I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs758763656, COSV70201738; called by muse, mutect2
- BIRC6 | c.13486C>T p.R4496W | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV70201627; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1899C>A p.F633L | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV63244998; called by muse, mutect2, varscan2
- BLM | c.3260T>G p.F1087C | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV61925107; called by muse, mutect2, varscan2
- BLNK | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV56409997; called by muse, mutect2, varscan2
- BLZF1 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 23/276 reads (8%) | catalogued as rs763271139, COSV61393623; called by muse, mutect2
- BMP3 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1435451372, COSV51081644; called by muse, mutect2
- BMPR1B | c.1151A>G p.D384G | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV52778958; called by muse, mutect2, varscan2
- BMS1 | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 65/321 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV65734385; called by muse, mutect2, varscan2
- BOD1L1 | c.9146C>T p.A3049V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs769512613, COSV50008166; called by muse, mutect2, varscan2
- BPIFB4 | c.251T>G p.I84S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100971462; called by muse, mutect2, varscan2
- BPTF | c.5815G>A p.E1939K | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs780605303, COSV58845552; called by muse, mutect2, varscan2
- BRCA2 | c.963A>C p.Q321H | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs276174927, BM1120885, COSV66456474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.10151G>A p.R3384Q | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); catalogued as rs80358397, COSV66336721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD8 | c.2758G>T p.E920* | Nonsense Mutation (SNP) | VAF 76/396 reads (19%) | catalogued as COSV50154806; called by muse, mutect2, varscan2
- BRDT | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303707788, COSV61770993; called by muse, mutect2, varscan2
- BRI3BP | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV58296524; called by muse, mutect2, varscan2
- BRINP1 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs866830541, COSV56301734, COSV99774824; called by muse, mutect2, varscan2
- BRINP1 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56304193; called by muse, mutect2, varscan2
- BRWD1 | c.4199T>G p.I1400S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60898347; called by muse, mutect2
- BRWD3 | c.3242C>A p.S1081Y | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.265); catalogued as COSV64750004; called by muse, mutect2, varscan2
- BRWD3 | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs898480653, COSV64750023; called by muse, mutect2, varscan2
- BRWD3 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV100955816, COSV64748283; called by muse, mutect2
- BRWD3 | c.485T>C p.F162S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV64750030; called by muse, mutect2, varscan2
- BTAF1 | c.3241G>T p.E1081* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | catalogued as COSV56435810; called by muse, mutect2, varscan2
- BTBD11 | c.1165C>A p.L389I | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.396); catalogued as COSV55027627; called by muse, mutect2, varscan2
- BTN3A2 | c.673T>C p.S225P | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV62687580; called by muse, mutect2, varscan2
- BTNL8 | c.461G>C p.C154S | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99180435; called by muse, mutect2, varscan2
- BUB1B | c.1187T>G p.M396R | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV55013957; called by muse, mutect2, varscan2
- BVES | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58948552, COSV58949077; called by muse, mutect2, varscan2
- C10orf90 | c.50G>T p.R17I | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV99503377; called by muse, mutect2
- C11orf54 | c.445T>G p.C149G | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.059); catalogued as COSV58681006; called by muse, mutect2, varscan2
- C12orf50 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV53896461; called by muse, mutect2, varscan2
- C12orf54 | c.280T>G p.L94V | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.112); catalogued as COSV58360522; called by muse, mutect2, varscan2
- C17orf75 | c.1032T>G p.H344Q | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56753145; called by muse, mutect2, varscan2
- C18orf54 | c.993C>A p.F331L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV55618555; called by muse, mutect2, varscan2
- C1S | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV100196630, COSV61071302; called by muse, mutect2, varscan2
- C1orf226 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63395851; called by muse, mutect2, varscan2
- C2CD3 | c.2257C>A p.H753N | Missense Mutation (SNP) | VAF 18/369 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV58090079; called by muse, mutect2
- C2orf42 | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV52451056; called by muse, mutect2
- C2orf49 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 38/251 reads (15%) | catalogued as COSV51528227; called by muse, mutect2, varscan2
- C2orf69 | c.953A>C p.K318T | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV60666781; called by muse, mutect2, varscan2
- C3orf14 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs368325890; called by muse, mutect2, varscan2
- C4BPA | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 32/115 reads (28%) | catalogued as COSV65536707; called by muse, mutect2, varscan2
- C6 | c.1161G>T p.K387N | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as COSV54712510; called by muse, mutect2, varscan2
- C6orf118 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.463); catalogued as COSV100023948; called by muse, mutect2
- C6orf136 | c.502G>A p.D168N (on ENST00000376473 / NM_001109938.3; = p.D34N on NM_145029.4) | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.944); catalogued as rs771615967, COSV53314831; called by muse, mutect2, varscan2
- C7 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV57473700; called by mutect2, varscan2
- C7orf33 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); catalogued as COSV100188975, COSV61023347; called by muse, mutect2, varscan2
- C8A | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV63484810, COSV63486233; called by muse, mutect2, varscan2
- C9 | c.876A>C p.K292N | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV54675659; called by muse, mutect2, varscan2
- CACHD1 | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 69/329 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.982); catalogued as COSV51555669; called by muse, mutect2, varscan2
- CACHD1 | c.2097C>A p.F699L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV51555678; called by muse, mutect2, varscan2
- CACNA1B | c.5178G>T p.L1726F | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53133119; called by muse, mutect2, varscan2
- CACNA1E | c.3351G>T p.K1117N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.079); catalogued as COSV62402253; called by muse, mutect2, varscan2
- CACNA1E | c.5143C>A p.L1715I | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62402257; called by muse, mutect2, varscan2
- CACNA1S | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1287772954, COSV100754794; called by muse, mutect2
- CACNA2D1 | c.2621T>G p.F874C (on ENST00000356253 / NM_001366867.1; = p.F862C on NM_000722.4) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62383163; called by muse, mutect2, varscan2
- CACNA2D1 | c.1376T>G p.V459G | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62383168; called by muse, mutect2
- CACNG3 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 29/291 reads (10%) | catalogued as COSV50072151, COSV50073264; called by muse, mutect2, varscan2
- CALD1 | c.2194A>C p.N732H (on ENST00000361675 / NM_033138.4; = p.N477H on NM_004342.7) | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62649478; called by muse, mutect2, varscan2
- CAPN2 | c.399A>C p.E133D | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54337291; called by muse, mutect2, varscan2
- CASP8AP2 | c.3708T>A p.N1236K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs763162486, COSV52748127; called by muse, mutect2, varscan2
- CASQ2 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54771562; called by muse, mutect2, varscan2
- CATSPERE | c.1628T>G p.F543C | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63679228; called by muse, mutect2, varscan2
- CAVIN2 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 36/170 reads (21%) | catalogued as COSV58424663; called by muse, mutect2, varscan2
- CBX3 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV61761318; called by muse, mutect2
- CCDC105 | c.1097A>G p.K366R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.35); catalogued as COSV99479796; called by muse, mutect2, varscan2
- CCDC112 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 23/124 reads (19%) | catalogued as COSV65473426; called by muse, mutect2, varscan2
- CCDC146 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs148455218, COSV53547020; called by muse, mutect2, varscan2
- CCDC158 | c.3056C>T p.S1019F | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs772436559, COSV66356458, COSV66357237; called by muse, mutect2, varscan2
- CCDC174 | c.953-1G>T p.X318_splice | Splice Site (SNP) | VAF 25/118 reads (21%) | catalogued as COSV100358480; called by muse, mutect2, varscan2
- CCDC32 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 41/194 reads (21%) | catalogued as rs1451366732, COSV63635134; called by muse, mutect2, varscan2
- CCDC66 | c.746C>A p.T249N (on ENST00000394672 / NM_001353147.1; = p.T215N on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58305505; called by muse, mutect2, varscan2
- CCDC68 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 25/143 reads (17%) | catalogued as COSV61604031; called by muse, mutect2, varscan2
- CCDC7 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as rs762095619, COSV53227495, COSV99511238; called by muse, mutect2, varscan2
- CCDC73 | c.1375+2T>C p.X459_splice | Splice Site (SNP) | VAF 17/80 reads (21%) | catalogued as COSV100066810; called by muse, mutect2, varscan2
- CCDC82 | c.1597T>G p.F533V | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV53594122; called by muse, mutect2
- CCDC82 | c.818A>C p.D273A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV53594132; called by muse, mutect2, varscan2
- CCDC82 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99567149; called by muse, mutect2
- CCDC83 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 22/177 reads (12%) | catalogued as rs1292149589, COSV54702941; called by muse, mutect2, varscan2
- CCER1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.41); catalogued as COSV62647167; called by muse, mutect2, varscan2
- CCNB3 | c.2800A>C p.N934H | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.554); catalogued as COSV52075463; called by muse, mutect2, varscan2
- CCNH | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99907217; called by muse, mutect2
- CCNL1 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 35/139 reads (25%) | catalogued as COSV55819736; called by muse, mutect2, varscan2
- CCNT2 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 26/97 reads (27%) | catalogued as COSV51472643; called by muse, mutect2, varscan2
- CCR4 | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58382816; called by muse, mutect2, varscan2
- CCR7 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs759676455, COSV55849835; called by muse, mutect2, varscan2
- CCR9 | c.38T>C p.M13T (on ENST00000357632 / NM_031200.3; = p.M1? on NM_006641.4) | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs749729442, COSV62940409; called by muse, mutect2, varscan2
- CCSER1 | c.435G>T p.K145N | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61441894; called by muse, mutect2, varscan2
- CCT6A | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); catalogued as rs754282148, COSV51906388; called by muse, mutect2, varscan2
- CCT6B | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58489925; called by muse, mutect2, varscan2
- CD101 | c.1604A>C p.K535T | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.494); catalogued as COSV56718962; called by muse, mutect2, varscan2
- CD101 | c.2407G>T p.E803* | Nonsense Mutation (SNP) | VAF 32/151 reads (21%) | catalogued as COSV56717297, COSV56718974; called by muse, mutect2, varscan2
- CD163 | c.2684G>T p.C895F | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63134234; called by muse, mutect2
- CD33 | c.175T>G p.Y59D | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51802680; called by muse, mutect2, varscan2
- CD34 | c.290C>A p.S97Y | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100178239; called by muse, mutect2
- CD4 | c.49+2T>C p.X17_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99163709; called by muse, mutect2, varscan2
- CD40LG | c.70T>G p.F24V | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV101033450; called by muse, mutect2
- CD69 | c.97C>A p.H33N | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV57303034; called by muse, mutect2, varscan2
- CD72 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV52411572; called by muse, mutect2, varscan2
- CDAN1 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768892869, COSV62332744; ClinVar: uncertain significance; called by mutect2, varscan2
- CDC14A | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs778051201, COSV60556049; called by muse, mutect2
- CDC27 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs1238314971, COSV50366964; called by muse, mutect2, varscan2
- CDC40 | c.844C>A p.H282N | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57010533; called by muse, mutect2, varscan2
- CDC73 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV66465795; called by muse, mutect2, varscan2
- CDH12 | c.1604A>C p.K535T | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV66386383, COSV66417587; called by muse, mutect2, varscan2
- CDH2 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 12/278 reads (4%) | catalogued as COSV52272668; called by muse, mutect2
- CDH20 | c.1373C>A p.S458Y | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV53012389; called by muse, mutect2, varscan2
- CDH23 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.995); catalogued as COSV54929104, COSV99818254; called by muse, mutect2, varscan2
- CDH8 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1055288839, COSV54849423; called by muse, mutect2
- CDH8 | c.1539C>A p.V513= | Splice Region (SNP) | VAF 9/110 reads (8%) | catalogued as COSV54863148; called by muse, mutect2
- CDH9 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as rs768954953, COSV50261316, COSV50266286; called by muse, mutect2, varscan2
- CDH9 | c.1092C>A p.F364L | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV99142374; called by muse, mutect2
- CDK11A | c.1889C>T p.S630L (on ENST00000378633 / NM_001313896.2; = p.S627L on NM_024011.4) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757293035, COSV52307726, COSV99319203; called by muse, mutect2
- CDK12 | c.2614C>T p.Q872* | Nonsense Mutation (SNP) | VAF 33/217 reads (15%) | catalogued as COSV71001376; called by muse, mutect2, varscan2
- CDK13 | c.3940G>T p.D1314Y | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as COSV51702419; called by muse, mutect2, varscan2
- CDK16 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV52092673; called by muse, mutect2, varscan2
- CDKL2 | c.1392T>G p.I464M | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.087); catalogued as COSV100276791; called by muse, mutect2
- CDKN1B | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as CM023042, COSV57430128; called by muse, mutect2, varscan2
- CDS1 | c.430A>C p.T144P | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV55688771; called by muse, mutect2, varscan2
- CDS1 | c.642C>T p.F214= | Splice Region (SNP) | VAF 22/134 reads (16%) | catalogued as rs375840719; called by muse, mutect2, varscan2
- CDYL2 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.368); catalogued as COSV73648034; called by muse, mutect2
- CEACAM7 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 12/255 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99137158; called by muse, mutect2
- CEACAM8 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 69/511 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV54990974, COSV99747576; called by muse, mutect2, varscan2
- CECR2 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52841089; called by muse, mutect2, varscan2
- CECR2 | c.2587C>T p.P863S (on ENST00000342247 / NM_001290047.2; = p.P680S on NM_001290046.1) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs1569154189, COSV52843909; called by muse, mutect2, varscan2
- CECR2 | c.3771C>A p.F1257L (on ENST00000342247 / NM_001290047.2; = p.F1073L on NM_001290046.1) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); catalogued as COSV99377339; called by muse, mutect2, varscan2
- CEMIP2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.223); catalogued as rs548434215, COSV65484674; called by muse, mutect2, varscan2
- CENPE | c.4036T>G p.S1346A | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV54383316; called by muse, mutect2, varscan2
- CENPF | c.3124A>C p.K1042Q | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV65276118; called by muse, mutect2, varscan2
- CENPF | c.8260G>T p.E2754* | Nonsense Mutation (SNP) | VAF 28/242 reads (12%) | catalogued as COSV65276121; called by muse, varscan2
- CENPF | c.8576A>G p.E2859G | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65276124, COSV65276821; called by muse, varscan2
- CENPU | c.1160T>G p.L387R | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55658220; called by muse, mutect2, varscan2
- CEP126 | c.1084A>C p.N362H | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV99680786; called by muse, mutect2
- CEP152 | c.2887G>T p.E963* | Nonsense Mutation (SNP) | VAF 34/168 reads (20%) | catalogued as COSV57860890; called by muse, mutect2, varscan2
- CEP152 | c.587A>C p.K196T | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV57860895; called by muse, mutect2, varscan2
- CEP164 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99632776; called by muse, mutect2
- CEP83 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1288256034, COSV60406406; called by muse, mutect2
- CEP95 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.235); catalogued as rs782452611, COSV101616308, COSV73609433; called by muse, mutect2, varscan2
- CERS3 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52570389; called by muse, mutect2, varscan2
- CERS3 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52565563; called by muse, mutect2, varscan2
- CFAP157 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs551402620, COSV58852076; called by mutect2, varscan2
- CFAP206 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as rs370690253; called by muse, mutect2
- CFAP206 | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV51535044; called by muse, mutect2, varscan2
- CFAP299 | c.589C>A p.L197I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100811630, COSV63881038; called by muse, mutect2, varscan2
- CFAP43 | c.4052C>A p.A1351D | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV63852902; called by muse, mutect2, varscan2
- CFAP43 | c.3500A>G p.K1167R | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs771756090, COSV63853585; called by muse, mutect2, varscan2
- CFAP47 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 153/476 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV52887176; called by muse, mutect2, varscan2
- CFAP61 | c.3242C>T p.A1081V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs189288996, COSV55635115; called by mutect2, varscan2
- CFAP91 | c.360-1G>T p.X120_splice | Splice Site (SNP) | VAF 17/60 reads (28%) | catalogued as COSV56343699, COSV99846736; called by muse, mutect2, varscan2
- CFAP94 | c.1016A>C p.K339T (on ENST00000320267 / NM_001352064.2; = p.K345T on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.355); catalogued as COSV57233691; called by muse, mutect2
- CFDP1 | c.403-1G>A p.X135_splice | Splice Site (SNP) | VAF 58/247 reads (23%) | catalogued as COSV52208578; called by muse, mutect2, varscan2
- CHD1 | c.3113G>T p.R1038I | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99399230; called by muse, mutect2
- CHD2 | c.4229A>C p.D1410A | Missense Mutation (SNP) | VAF 41/377 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV67711002; called by muse, mutect2
- CHD4 | c.1676G>A p.R559Q (on ENST00000357008 / NM_001363606.2; = p.R572Q on NM_001273.5) | Missense Mutation (SNP) | VAF 56/407 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58904370; called by muse, mutect2, varscan2
- CHD4 | c.1590C>A p.F530L (on ENST00000357008 / NM_001363606.2; = p.F543L on NM_001273.5) | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as COSV100537577; called by muse, varscan2
- CHD8 | c.4179T>G p.N1393K (on ENST00000646647 / NM_001170629.2; = p.N1114K on NM_020920.4) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV63219305; called by muse, mutect2
- CHD9 | c.5393A>G p.N1798S | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1381047417, COSV54612189; called by muse, mutect2, varscan2
- CHGB | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs560272361, COSV66760876; called by muse, mutect2, varscan2
- CHL1 | c.2419G>T p.D807Y (on ENST00000397491 / NM_001253387.1; = p.D823Y on NM_006614.4) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56596809; called by muse, mutect2, varscan2
- CHRDL1 | c.1005C>A p.F335L (on ENST00000372045; = p.F341L on NM_145234.4) | Missense Mutation (SNP) | VAF 58/302 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV54326274; called by muse, mutect2, varscan2
- CHRDL1 | c.212G>A p.R71Q (on ENST00000372045; = p.R77Q on NM_145234.4) | Missense Mutation (SNP) | VAF 70/375 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs149609884, COSV54326285, COSV99488325; called by muse, mutect2, varscan2
- CHRNA6 | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371233399; called by muse, mutect2, varscan2
- CHST1 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); catalogued as rs1391430094, COSV100346531, COSV57324224; called by muse, mutect2, varscan2
- CHST9 | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 92/430 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52439630, COSV52441080; called by muse, mutect2, varscan2
- CIBAR2 | c.546T>G p.F182L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.162); catalogued as COSV73320638; called by muse, mutect2, varscan2
- CIT | c.3547C>T p.R1183W | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs773906531, COSV55870133; called by muse, mutect2, varscan2
- CKAP2L | c.879G>T p.K293N | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV100198560, COSV56696949; called by muse, mutect2, varscan2
- CLCA1 | c.1877T>G p.V626G | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52328793; called by muse, varscan2
- CLCA4 | c.1447C>A p.L483I | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1441848033, COSV99760322; called by muse, mutect2
- CLCN5 | c.520A>C p.K174Q | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100259924; called by muse, mutect2
- CLCN5 | c.1044G>T p.K348N | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV56583304, COSV56585060; called by muse, mutect2, varscan2
- CLDN16 | c.33C>A p.F11L | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV53228245, COSV99290046; called by muse, mutect2
- CLDN2 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 71/261 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.869); catalogued as COSV61020942; called by muse, mutect2, varscan2
- CLDN8 | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs994122095, COSV54526331; called by muse, mutect2, varscan2
- CLDN8 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 13/92 reads (14%) | catalogued as COSV54526083, COSV54526345; called by muse, mutect2, varscan2
- CLEC16A | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1567530329, COSV68500406; called by muse, mutect2, varscan2
- CLEC4A | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.071); catalogued as COSV57562189; called by muse, mutect2, varscan2
- CLEC4F | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.808); catalogued as COSV99713622; called by muse, varscan2
- CLGN | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 10/155 reads (6%) | catalogued as COSV57774477; called by muse, mutect2
- CLHC1 | c.365+1G>T p.X122_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100811477; called by muse, mutect2, varscan2
- CLIP1 | c.2017G>A p.E673K (on ENST00000620786 / NM_001247997.1; = p.E662K on NM_002956.2) | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs201352592; called by muse, mutect2, varscan2
- CLK3 | c.1243C>A p.L415I (on ENST00000395066 / NM_001130028.1; = p.L267I on NM_003992.4) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.353); catalogued as COSV59340801; called by muse, mutect2, varscan2
- CLMN | c.1696T>G p.F566V | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV54183809; called by muse, mutect2, varscan2
- CLYBL | c.534T>G p.N178K | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV59223623; called by muse, mutect2, varscan2
- CMSS1 | c.695T>G p.F232C | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV70438865; called by muse, mutect2, varscan2
- CMYA5 | c.2884A>C p.T962P | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV71406984; called by muse, mutect2
- CMYA5 | c.4237C>A p.L1413I | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV71406988; called by muse, mutect2, varscan2
- CMYA5 | c.5242T>G p.L1748V | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.409); catalogued as rs749328624, COSV71406992; called by muse, mutect2
- CMYA5 | c.6628G>A p.V2210I | Missense Mutation (SNP) | VAF 95/508 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as rs751513243, COSV71404031; called by muse, varscan2
- CMYA5 | c.9711T>G p.Y3237* | Nonsense Mutation (SNP) | VAF 76/339 reads (22%) | catalogued as COSV71406998; called by muse, mutect2, varscan2
- CMYA5 | c.10454G>T p.R3485M | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV101483947; called by muse, mutect2
- CNGA1 | c.1979A>C p.K660T | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV62054982; called by muse, mutect2, varscan2
- CNGA1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198139574, COSV62053154; called by muse, mutect2, varscan2
- CNGA2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 63/281 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780670790, COSV61705135; called by muse, mutect2, varscan2
- CNGB3 | c.2062C>A p.L688I | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV100181507; called by muse, mutect2
- CNOT6L | c.800C>A p.S267* (on ENST00000504123 / NM_001286790.2; = p.S262* on NM_144571.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99361551; called by muse, mutect2, varscan2
- CNPY1 | c.44G>T p.R15I | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs1200944745, COSV58787694; called by muse, mutect2, varscan2
- CNPY2 | c.453C>A p.F151L | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.017); catalogued as rs1363961259, COSV56264599; called by muse, mutect2, varscan2
- CNTF | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100284377; called by muse, mutect2
- CNTN1 | c.971G>T p.R324I | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs148624625, COSV61641574; called by muse, mutect2, varscan2
- CNTN1 | c.1678T>G p.F560V | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV61641583; called by muse, mutect2, varscan2
- CNTN5 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as COSV54324377; called by muse, mutect2, varscan2
- CNTN5 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.774); catalogued as rs1010130853, COSV54303038, COSV99676123; called by muse, mutect2, varscan2
- COBLL1 | c.2334G>T p.K778N (on ENST00000392717; = p.K740N on NM_014900.5) | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs377161034, COSV52074719; called by muse, mutect2, varscan2
- COG4 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs149620212; called by muse, mutect2, varscan2
- COL11A2 | c.2323G>A p.G775R (on ENST00000341947 / NM_080680.3; = p.G668R on NM_080679.2) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59498606; called by muse, mutect2, varscan2
- COL12A1 | c.7576G>A p.A2526T | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV59399258; called by muse, mutect2, varscan2
- COL14A1 | c.4771G>A p.A1591T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs370064596; called by muse, mutect2, varscan2
- COL24A1 | c.1127A>C p.N376T | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV65308530; called by muse, mutect2, varscan2
- COLGALT2 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs757064316, COSV62299839; called by mutect2, varscan2
- COMMD2 | c.290A>G p.K97R | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV101511896; called by muse, mutect2
- COPS6 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57997209; called by muse, mutect2, varscan2
- CORO2B | c.1187C>A p.S396Y | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55954398; called by muse, mutect2, varscan2
- CP | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 38/228 reads (17%) | catalogued as COSV52829774; called by muse, mutect2, varscan2
- CPA6 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775233588, COSV52721227; called by muse, mutect2, varscan2
- CPAMD8 | c.1255G>A p.D419N (on ENST00000651564; = p.D372N on NM_015692.5) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370768920, COSV52231899, COSV99359178; called by mutect2, varscan2
- CPD | c.3878T>G p.I1293R | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV56713958; called by muse, mutect2, varscan2
- CPEB1 | c.308C>A p.S103Y (on ENST00000617958; = p.S43Y on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV71604536; called by muse, mutect2
- CPED1 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 19/90 reads (21%) | catalogued as rs202229385, COSV60005795; called by muse, mutect2, varscan2
- CPED1 | c.2314C>A p.L772M | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV60012901; called by muse, mutect2
- CPQ | c.92G>T p.R31M | Missense Mutation (SNP) | VAF 90/414 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV55150888; called by muse, mutect2, varscan2
- CPQ | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55150894; called by muse, mutect2, varscan2
- CPS1 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV51801791; called by muse, mutect2, varscan2
- CPXCR1 | c.890G>T p.S297I | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV52160835; called by muse, mutect2, varscan2
- CPXM1 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as COSV66045924; called by muse, mutect2, varscan2
- CPXM2 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944271451, COSV53860832; called by muse, mutect2
- CPXM2 | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53864829, COSV53871457; called by muse, mutect2, varscan2
- CR1 | c.3854T>C p.V1285A | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as COSV65459558; called by muse, mutect2, varscan2
- CR2 | c.2402A>C p.K801T | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV65508348; called by muse, mutect2, varscan2
- CRIM1 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54866922; called by muse, mutect2, varscan2
- CRNKL1 | c.2227C>T p.R743* | Nonsense Mutation (SNP) | VAF 84/533 reads (16%) | catalogued as COSV58548136; called by muse, mutect2, varscan2
- CRTAM | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs148256561, COSV99911885; called by muse, mutect2, varscan2
- CSMD1 | c.1885G>T p.D629Y (on ENST00000520002; = p.D628Y on NM_033225.6) | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59298103, COSV59341653; called by muse, mutect2
- CSMD2 | c.1985A>G p.H662R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV53926304; called by muse, mutect2, varscan2
- CSMD3 | c.4261G>T p.E1421* (on ENST00000297405 / NM_001363185.1; = p.E1317* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 8/128 reads (6%) | catalogued as COSV99828533; called by muse, mutect2
- CSMD3 | c.3578G>A p.R1193Q (on ENST00000297405 / NM_001363185.1; = p.R1089Q on NM_052900.3) | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs1323845975, COSV52111209; called by muse, mutect2, varscan2
- CSRNP1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200194534, COSV56188870; called by muse, mutect2, varscan2
- CTAGE1 | c.197T>G p.F66C | Missense Mutation (SNP) | VAF 25/531 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV101194468; called by muse, mutect2
- CTAGE6 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 30/321 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as COSV101417824; called by muse, mutect2, varscan2
- CTAGE6 | c.1049A>C p.E350A | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV101417825; called by muse, mutect2, varscan2
- CTCFL | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772424129, COSV54770682; called by muse, mutect2, varscan2
- CTNNA2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.948); catalogued as rs574924497, COSV63579296; called by muse, mutect2, varscan2
- CTNNA3 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 18/302 reads (6%) | catalogued as COSV101047402, COSV65621924; called by muse, mutect2
- CTNNB1 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62705582; called by muse, mutect2, varscan2
- CTPS2 | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 15/321 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.06); catalogued as COSV100826732; called by muse, mutect2
- CTTNBP2 | c.4514C>A p.S1505Y | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.11); catalogued as COSV50414575; called by muse, mutect2, varscan2
- CTXN3 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1225404731, COSV65218585; called by muse, mutect2, varscan2
- CWF19L1 | c.738G>T p.M246I | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV100821474; called by muse, mutect2
- CWF19L2 | c.992A>C p.K331T | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs550302523, COSV56514998; called by muse, varscan2
- CXCL5 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as COSV56018371; called by muse, mutect2
- CXorf58 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 60/301 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.276); catalogued as COSV64858251, COSV64858484; called by muse, mutect2, varscan2
- CYB5R4 | c.879C>A p.F293L | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as COSV63751204; called by muse, mutect2, varscan2
- CYLC1 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV61413231; called by muse, mutect2, varscan2
- CYLC1 | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61413240; called by muse, mutect2, varscan2
- CYP11B1 | c.426G>T p.L142F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52828381; called by muse, mutect2, varscan2
- CYP2C18 | c.706A>C p.N236H | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV53671095; called by muse, mutect2, varscan2
- CYP2U1 | c.1127-1G>T p.X376_splice | Splice Site (SNP) | VAF 22/80 reads (28%) | catalogued as COSV60548252; called by muse, mutect2, varscan2
- CYP39A1 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 36/268 reads (13%) | catalogued as COSV51496884; called by muse, mutect2, varscan2
- CYP4F12 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 38/168 reads (23%) | catalogued as COSV61174674; called by muse, mutect2, varscan2
- CYP4F22 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761963345, COSV54107667; called by muse, mutect2, varscan2
- CYSLTR2 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV56166243; called by muse, mutect2, varscan2
- DAAM1 | c.2558A>G p.N853S | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as COSV62837487; called by muse, mutect2
- DAB1 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 71/263 reads (27%) | catalogued as COSV59730609; called by muse, mutect2, varscan2
- DAPK1 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs772431146, COSV63788568, COSV63788808; called by muse, mutect2, varscan2
- DAW1 | c.1004G>T p.R335I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV59366530, COSV59369610; called by muse, mutect2, varscan2
- DCAF10 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs767043246, COSV54288016; called by muse, mutect2, varscan2
- DCAF4L2 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV60477184, COSV60480639; called by muse, mutect2, varscan2
- DCAF7 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV60407981; called by muse, mutect2, varscan2
- DCDC1 | c.1987G>T p.D663Y | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV100662970; called by muse, mutect2, varscan2
- DCDC1 | c.398G>T p.R133I | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100662972; called by muse, mutect2
- DCLRE1A | c.1576T>G p.L526V | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV63749036; called by muse, mutect2, varscan2
- DCLRE1C | c.4A>C p.S2R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63184134; called by muse, mutect2, varscan2
- DCN | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs751102416, COSV50007765, COSV50008884; called by muse, mutect2, varscan2
- DCT | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1274035879, COSV65469838; called by muse, mutect2, varscan2
- DDB2 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs375649516; called by muse, mutect2, varscan2
- DDR2 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 74/289 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63372039; called by muse, mutect2, varscan2
- DDX24 | c.1654G>T p.D552Y | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100427863; called by muse, mutect2
- DDX60L | c.91A>C p.N31H | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV99487177; called by muse, mutect2
- DEFB129 | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as COSV55731370, COSV99857384; called by muse, mutect2
- DEFB136 | c.123C>A p.F41L | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV66363943; called by muse, mutect2, varscan2
- DEGS1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60379532; called by muse, mutect2, varscan2
- DENND4A | c.3914C>A p.S1305* | Nonsense Mutation (SNP) | VAF 13/123 reads (11%) | catalogued as COSV71266321; called by muse, mutect2, varscan2
- DENND5B | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1488658943, COSV60900651, COSV60902248; called by muse, mutect2, varscan2
- DEPDC1B | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV54011199, COSV54013195; called by muse, mutect2
- DEUP1 | c.1729C>A p.L577I | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769163934, COSV53213533; called by muse, mutect2, varscan2
- DGAT2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs140088423; called by mutect2, varscan2
- DGKD | c.397G>T p.E133* (on ENST00000264057 / NM_152879.3; = p.E89* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as rs199985859, COSV51038365; called by muse, mutect2, varscan2
- DGKH | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs370149879; called by muse, mutect2, varscan2
- DGKI | c.3040C>A p.L1014M | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55957851; called by muse, mutect2, varscan2
- DGKK | c.2921C>A p.S974Y | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101052930; called by muse, mutect2, varscan2
- DHFR | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1456478807, COSV71485479; called by muse, mutect2, varscan2
- DHRS2 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs562246921, COSV51632626; called by muse, mutect2
- DHX40 | c.113-1G>A p.X38_splice | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99232812; called by muse, mutect2, varscan2
- DHX58 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV52426682; called by muse, mutect2, varscan2
- DIAPH1 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1014304479, COSV99526077; called by muse, mutect2
- DIAPH1 | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 38/716 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV99526083; called by muse, mutect2
- DIAPH2 | c.1919G>T p.R640I | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV61260070; called by muse, mutect2, varscan2
- DICER1 | c.2876A>C p.K959T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV100602677, COSV58620076; called by muse, mutect2
- DKC1 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65729807; called by muse, mutect2, varscan2
- DKK1 | c.632A>C p.K211T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100906508; called by muse, mutect2, varscan2
- DLL3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770966935, COSV52693963; called by muse, mutect2, varscan2
- DMC1 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745397961, COSV53258386; called by muse, mutect2, varscan2
- DMD | c.5627C>A p.S1876Y | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV63767582, COSV63791573; called by muse, mutect2
- DMD | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55881175; called by muse, mutect2, varscan2
- DMGDH | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs369589026; called by muse, mutect2, varscan2
- DMXL1 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1225994331, COSV60714858; called by muse, mutect2, varscan2
- DMXL1 | c.6206C>T p.A2069V | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV60714864; called by muse, mutect2, varscan2
- DNAH10 | c.12799G>T p.E4267* (on ENST00000409039; = p.E4206* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | catalogued as COSV53020358; called by muse, mutect2, varscan2
- DNAH11 | c.3270A>C p.E1090D | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as COSV100178107; called by muse, mutect2
- DNAH11 | c.9346C>A p.L3116I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60963286; called by muse, mutect2, varscan2
- DNAH5 | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 62/271 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs200704983, COSV54220726; called by muse, mutect2, varscan2
- DNAH6 | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 31/180 reads (17%) | catalogued as COSV52868108; called by muse, mutect2, varscan2
- DNAH8 | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100543959; called by muse, mutect2
- DNAH8 | c.4183G>T p.D1395Y | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV59458288; called by muse, mutect2, varscan2
- DNAH8 | c.9973G>T p.V3325L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as COSV59458305; called by muse, mutect2, varscan2
- DNAH9 | c.2408G>T p.R803I | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs753142472, COSV52336899, COSV52340773; called by muse, varscan2
- DNAH9 | c.11430C>A p.F3810L | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs956358261, COSV52343252, COSV52347043; called by muse, mutect2
- DNAI3 | c.278T>G p.I93S | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV54000603, COSV54003769; called by muse, mutect2, varscan2
- DNAI3 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54005751, COSV54007468; called by muse, mutect2
- DNAJC10 | c.2250C>A p.F750L | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV51135745; called by muse, mutect2, varscan2
- DNAJC13 | c.3481G>T p.D1161Y | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53453197; called by muse, mutect2
- DNAJC18 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs201230885, COSV57415758; called by muse, mutect2, varscan2
- DNAJC2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1044150804, COSV50791729; called by muse, mutect2, varscan2
- DNAJC25 | c.454A>C p.I152L | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.203); catalogued as COSV57957125; called by muse, mutect2, varscan2
- DNAJC28 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 24/194 reads (12%) | catalogued as rs138072076; called by muse, mutect2, varscan2
- DNAJC5B | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 40/161 reads (25%) | catalogued as COSV52538186; called by muse, mutect2, varscan2
- DNM1 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1420929016, COSV57852937; called by muse, mutect2, varscan2
- DNM1L | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751127554, COSV56771938; called by muse, mutect2, varscan2
- DNMT3B | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs1282274366, COSV52419727, COSV99145838; called by muse, mutect2, varscan2
- DNTT | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as COSV64523216; called by muse, mutect2, varscan2
- DOCK2 | c.879T>G p.I293M | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV56967314; called by muse, mutect2, varscan2
- DOCK2 | c.4940C>A p.S1647Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV56967327; called by muse, mutect2, varscan2
- DOCK3 | c.708C>A p.F236L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.54); catalogued as COSV56512700; called by mutect2, varscan2
- DOCK3 | c.1128T>C p.G376= | Splice Region (SNP) | VAF 22/74 reads (30%) | catalogued as rs1187432954, COSV56530654; called by muse, mutect2, varscan2
- DOCK3 | c.2794C>T p.R932W | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs1228911523, COSV56516212; called by muse, mutect2, varscan2
- DOCK4 | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.262); catalogued as COSV70322791; called by muse, mutect2, varscan2
- DOCK7 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as rs1408421974, COSV52014866; called by muse, mutect2
- DOCK9 | c.70A>G p.M24V | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.266); catalogued as COSV100238395; called by muse, mutect2, varscan2
- DOK6 | c.199A>C p.N67H | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV101234349; called by muse, mutect2
- DPP10 | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100060958; called by muse, mutect2
- DPP10 | c.1875G>T p.K625N | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV59696363; called by muse, mutect2, varscan2
- DPPA2 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV101524775, COSV72118156; called by muse, mutect2, varscan2
- DQX1 | c.1797C>A p.Y599* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV52046385; called by muse, mutect2, varscan2
- DRC1 | c.1881G>T p.K627N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV55507511; called by muse, mutect2, varscan2
- DRP2 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 68/409 reads (17%) | catalogued as COSV65810778; called by muse, varscan2
- DSC1 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV57147530; called by muse, mutect2, varscan2
- DSCAML1 | c.4102C>T p.R1368W (on ENST00000321322; = p.R1308W on NM_020693.4) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58381992; called by muse, mutect2, varscan2
- DSG4 | c.928C>A p.L310I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.028); catalogued as rs886053705, COSV57388902; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.2747A>C p.K916T | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1554107730, COSV101131199; ClinVar: uncertain significance; called by muse, mutect2
- DST | c.14492A>G p.E4831G (on ENST00000361203 / NM_001374722.1; = p.E2419G on NM_015548.5) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV55023108; called by muse, mutect2, varscan2
- DST | c.11413G>A p.E3805K (on ENST00000361203 / NM_001374722.1; = p.E1393K on NM_015548.5) | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV55008432, COSV55037893; called by muse, mutect2
- DST | c.10601A>C p.K3534T | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99752867; called by muse, mutect2, varscan2
- DST | c.5131G>T p.D1711Y | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99752872; called by muse, mutect2, varscan2
- DUOX2 | c.2640C>A p.F880L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs1160134983, COSV66530507; called by muse, mutect2, varscan2
- DUSP6 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV54378306; called by muse, mutect2, varscan2
- DYNC2LI1 | c.522T>G p.I174M | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as COSV53184043; called by muse, mutect2, varscan2
- DYNC2LI1 | c.634T>C p.Y212H | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV53184053; called by muse, mutect2, varscan2
- DYTN | c.593C>A p.S198Y | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65970739; called by muse, mutect2, varscan2
- EBF2 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV68776252; called by muse, mutect2, varscan2
- ECD | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV65900333; called by muse, mutect2, varscan2
- ECT2L | c.2040G>T p.M680I | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV62885467; called by muse, mutect2, varscan2
- ECT2L | c.2532C>A p.F844L | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99238511; called by muse, mutect2
- EEF1A1 | c.1133A>C p.K378T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV58550050; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1911A>C p.E637D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV62568661; called by muse, mutect2
- EFCAB12 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58177126; called by muse, mutect2, varscan2
- EFCAB13 | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV58949882; called by muse, mutect2, varscan2
- EFCAB5 | c.416T>G p.L139R | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as COSV57932319; called by muse, mutect2, varscan2
- EFHB | c.2219G>T p.R740I | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV55549696; called by muse, mutect2, varscan2
- EFHC2 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746108363, COSV69554240; called by muse, mutect2, varscan2
- EIF3J | c.208A>C p.K70Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as COSV56009112; called by muse, mutect2, varscan2
- ELF4 | c.1741A>G p.T581A | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57453320; called by muse, mutect2, varscan2
- ELF5 | c.541G>A p.D181N (on ENST00000312319 / NM_198381.2; = p.D171N on NM_001422.4) | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56629290; called by muse, mutect2, varscan2
- ELL2 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 28/379 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs983451634, COSV52983466; called by muse, mutect2
- ELL3 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs769387331, COSV55857066, COSV55857265; called by muse, mutect2, varscan2
- ELOA2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs765481551, COSV55300627; called by muse, mutect2, varscan2
- ELOVL4 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63954165; called by muse, mutect2, varscan2
- EMX1 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777186799, COSV50689363; called by muse, mutect2, varscan2
- ENAM | c.1454T>G p.F485C | Missense Mutation (SNP) | VAF 63/303 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV68536318; called by muse, mutect2, varscan2
- ENDOD1 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.212); catalogued as rs200901212, COSV53589997, COSV99566557; called by muse, mutect2, varscan2
- ENOX2 | c.10G>T p.D4Y | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs1180506827, COSV100584545; called by muse, mutect2
- EPB41L4A | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.559); catalogued as rs772237814, COSV54863025; called by muse, mutect2, varscan2
- EPG5 | c.5682A>G p.I1894M | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.668); catalogued as rs372631564; called by mutect2, varscan2
- EPHA3 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV60712551; called by muse, mutect2, varscan2
- EPHA7 | c.609G>T p.K203N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65169707, COSV65170837; called by muse, mutect2, varscan2
- EPHB1 | c.1847T>C p.V616A | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.137); catalogued as COSV67664254; called by muse, varscan2
- EPHX4 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64889663; called by muse, mutect2, varscan2
- EPS15 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs777135649, COSV65531582; called by muse, mutect2, varscan2
- ERBB4 | c.1195A>G p.T399A | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99618974; called by muse, mutect2
- ERBIN | c.1925C>A p.S642Y | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52312995, COSV52329064; called by muse, mutect2, varscan2
- ERCC6L | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339227994, COSV57819781; called by muse, mutect2, varscan2
- ERCC6L2 | c.504A>C p.K168N | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56631896; called by muse, mutect2
- ERICH3 | c.2923C>A p.L975I | Missense Mutation (SNP) | VAF 116/351 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV58610538; called by muse, mutect2, varscan2
- ERICH3 | c.1223C>A p.S408Y | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV58610549; called by muse, mutect2, varscan2
- ERICH3 | c.316-1G>T p.X106_splice | Splice Site (SNP) | VAF 49/219 reads (22%) | catalogued as COSV100443777, COSV58602622; called by muse, mutect2, varscan2
- ERICH6 | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.49); catalogued as COSV99901446; called by muse, mutect2
- ERN2 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV56834993; called by muse, mutect2, varscan2
- ESCO1 | c.1023G>T p.L341F | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV52520599; called by muse, mutect2, varscan2
- ESF1 | c.1904T>C p.F635S | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52522151; called by muse, mutect2, varscan2
- ESF1 | c.562T>G p.L188V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52522162; called by muse, mutect2
- ESRRG | c.1078A>G p.K360E | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.22); catalogued as COSV63167259; called by muse, mutect2, varscan2
- ESX1 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65423892; called by muse, mutect2, varscan2
- ETAA1 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as COSV55473813; called by muse, mutect2, varscan2
- ETF1 | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV62127645; called by muse, mutect2, varscan2
- ETF1 | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62127652; called by muse, mutect2, varscan2
- EVA1A | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as rs761924250, COSV52059603; called by muse, mutect2, varscan2
- EVI2B | c.1248T>G p.D416E | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV58364356; called by muse, mutect2, varscan2
- EVI2B | c.600T>G p.Y200* | Nonsense Mutation (SNP) | VAF 71/471 reads (15%) | catalogued as COSV58364367; called by muse, mutect2, varscan2
- EVX2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV57963938; called by muse, mutect2
- EXOG | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.222); catalogued as rs368056983; called by muse, mutect2
- EXPH5 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs780333058, COSV56203534; called by muse, mutect2, varscan2
- F2RL2 | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV56971084; called by muse, mutect2, varscan2
- F5 | c.2448G>T p.K816N | Missense Mutation (SNP) | VAF 83/405 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV63125430; called by muse, mutect2, varscan2
- F5 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as CM950384, COSV63125434; called by muse, mutect2, varscan2
- F5 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV63120327; called by muse, mutect2, varscan2
- F8 | c.3709A>G p.T1237A | Missense Mutation (SNP) | VAF 46/386 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs1286737779, COSV64275111; called by muse, mutect2, varscan2
- F8 | c.3583C>A p.L1195I | Missense Mutation (SNP) | VAF 17/345 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV100811378; called by muse, mutect2
- FABP7 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs903265251, COSV62956573; called by muse, mutect2, varscan2
- FAM122B | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 21/149 reads (14%) | catalogued as COSV53231578; called by muse, mutect2, varscan2
- FAM135A | c.254A>G p.D85G (on ENST00000370479 / NM_001351599.1; = p.D42G on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52053925; called by muse, mutect2, varscan2
- FAM135B | c.3131T>G p.F1044C | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52734565, COSV52750348; called by muse, mutect2, varscan2
- FAM13A | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1474941643, COSV52005645; called by muse, mutect2, varscan2
- FAM13B | c.2110C>A p.H704N | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV50368118; called by muse, mutect2, varscan2
- FAM13B | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV99221132; called by muse, mutect2
- FAM169A | c.51A>C p.E17D | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65846776; called by muse, mutect2, varscan2
- FAM170A | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100088841; called by muse, mutect2
- FAM184A | c.2782G>T p.D928Y | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100137538; called by muse, mutect2
- FAM184A | c.2106G>T p.Q702H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58855786; called by muse, mutect2, varscan2
- FAM184A | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | catalogued as COSV58855793; called by muse, mutect2, varscan2
- FAM184A | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV58855802; called by muse, mutect2, varscan2
- FAM209B | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100990936; called by muse, mutect2
- FAM217B | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs200508394, COSV62564615; called by muse, mutect2, varscan2
- FAM227B | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV54813544; called by muse, mutect2, varscan2
- FAM227B | c.71A>C p.K24T | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as COSV54813553; called by muse, mutect2, varscan2
- FAM237A | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV69305139; called by muse, mutect2, varscan2
- FAM47A | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as rs1426442027, COSV60494190; called by muse, mutect2, varscan2
- FAM81A | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 18/220 reads (8%) | catalogued as rs1353344073, COSV55677330; called by muse, mutect2
- FAM90A1 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV56713019; called by muse, mutect2, varscan2
- FAM9B | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 16/85 reads (19%) | catalogued as COSV59119752; called by muse, mutect2, varscan2
- FAN1 | c.2090G>T p.R697I | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs749900780, COSV62951391; called by muse, mutect2
- FANCD2 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as rs1004943548, COSV55040760; called by muse, mutect2, varscan2
- FANCM | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV57502713; called by muse, mutect2, varscan2
- FANCM | c.2381T>G p.F794C | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.408); catalogued as COSV57502721; called by muse, mutect2
- FANK1 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as COSV64156739; called by muse, mutect2, varscan2
- FASTKD1 | c.1584G>T p.M528I | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV71624405; called by muse, mutect2, varscan2
- FASTKD3 | c.1367C>A p.S456* | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | catalogued as COSV52942579, COSV52944869; called by muse, mutect2, varscan2
- FAT3 | c.12661G>A p.V4221I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749339528, COSV53082658; called by muse, mutect2, varscan2
- FAT4 | c.14852A>C p.D4951A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58692774; called by muse, mutect2, varscan2
- FAU | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV54195311; called by mutect2, varscan2
- FBN1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1060501079, COSV57321058; called by muse, mutect2, varscan2
- FBXO11 | c.2550C>A p.F850L (on ENST00000403359 / NM_001190274.2; = p.F766L on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52282096; called by muse, mutect2, varscan2
- FBXO21 | c.984C>A p.F328L | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57973638; called by muse, mutect2, varscan2
- FBXO34 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775419301, COSV58254251; called by muse, varscan2
- FBXO38 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 10/180 reads (6%) | catalogued as COSV99693232; called by muse, mutect2
- FBXO47 | c.166T>G p.L56V | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65242078; called by muse, mutect2, varscan2
- FBXO6 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.189); catalogued as rs1258160159, COSV65100862; called by muse, mutect2, varscan2
- FBXW11 | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.544); catalogued as COSV51610769; called by muse, mutect2, varscan2
- FBXW2 | c.390G>T p.M130I | Missense Mutation (SNP) | VAF 57/282 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.38); catalogued as COSV61597350; called by muse, mutect2, varscan2
- FCGR3A | c.293A>G p.D98G | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749283416, COSV63459889; called by muse, mutect2, varscan2
- FCHSD1 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs558644593, COSV51837764; called by muse, mutect2, varscan2
- FCRL2 | c.1518G>T p.K506N | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63834068, COSV63834087; called by muse, mutect2, varscan2
- FCRL5 | c.2079T>G p.F693L | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62516280; called by muse, mutect2, varscan2
- FER1L6 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs753364876, COSV67549608; called by muse, mutect2, varscan2
- FER1L6 | c.5037C>A p.F1679L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV67548944; called by muse, mutect2, varscan2
- FGD1 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64309022; called by muse, mutect2, varscan2
- FGD6 | c.3530C>T p.A1177V | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377183623; called by muse, mutect2, varscan2
- FGL1 | c.571T>G p.F191V | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV67712153; called by muse, varscan2
- FIGNL1 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866389991, COSV63553701; called by muse, mutect2, varscan2
- FKBP7 | c.21C>A p.F7L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV51845985, COSV51846743; called by muse, mutect2, varscan2
- FLII | c.2031G>T p.E677D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); catalogued as COSV100375160; called by muse, mutect2, varscan2
- FLRT2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58144608; called by muse, mutect2
- FLVCR2 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV53163037; called by muse, mutect2, varscan2
- FMN1 | c.4121C>A p.S1374Y (on ENST00000616417 / NM_001277313.2; = p.S1151Y on NM_001103184.4) | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.825); catalogued as COSV57925879; called by muse, mutect2, varscan2
- FMN1 | c.2617G>A p.A873T (on ENST00000616417 / NM_001277313.2; = p.A650T on NM_001103184.4) | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.552); catalogued as rs372119445; called by muse, mutect2
- FMR1 | c.1096T>C p.S366P | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs1557179888; called by muse, mutect2
- FNIP2 | c.3196A>C p.S1066R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52441570; called by muse, mutect2, varscan2
- FOCAD | c.348A>C p.E116D | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.376); catalogued as COSV58097397, COSV58102164; called by muse, mutect2, varscan2
- FOXN2 | c.414T>G p.I138M | Missense Mutation (SNP) | VAF 74/331 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61318748; called by muse, mutect2, varscan2
- FOXN4 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs373055287; called by muse, mutect2, varscan2
- FOXP2 | c.1481A>G p.N494S | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1300216902, COSV100646387; called by muse, mutect2
- FPGT-TNNI3K | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200196531, COSV58558224; called by muse, mutect2
- FPR3 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 26/385 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100200602; called by muse, mutect2
- FREM1 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV66519862; called by muse, mutect2, varscan2
- FREM1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV100772185; called by muse, mutect2
- FREM1 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1331014776, COSV66525765; called by muse, mutect2
- FRK | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs753596132, COSV73384053; called by muse, mutect2, varscan2
- FRMD7 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 65/478 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV53746529; called by muse, mutect2, varscan2
- FRMPD1 | c.1133C>A p.S378Y | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV66700930; called by muse, mutect2, varscan2
- FRMPD4 | c.1068C>T p.I356= | Splice Region (SNP) | VAF 38/186 reads (20%) | catalogued as rs1040001720, COSV66217578; called by muse, mutect2, varscan2
- FRRS1 | c.859-2A>G p.X287_splice | Splice Site (SNP) | VAF 32/166 reads (19%) | catalogued as COSV99789760; called by muse, mutect2, varscan2
- FRY | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as COSV100969939, COSV66572854, COSV66580479; called by muse, mutect2, varscan2
- FRYL | c.3428C>A p.S1143Y | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV99976317; called by muse, mutect2
- FSHB | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV54222310; called by muse, mutect2
- FSIP1 | c.1624C>G p.L542V | Missense Mutation (SNP) | VAF 76/312 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV63225467; called by muse, mutect2
- FSTL4 | c.706C>A p.R236S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV54770553, COSV54775580; called by mutect2, varscan2
- FTSJ3 | c.630C>A p.F210L | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.243); catalogued as rs1456609717, COSV59562935; called by muse, mutect2, varscan2
- FUNDC2 | c.540del p.F180Lfs*52 | Frame Shift Del (DEL) | VAF 40/297 reads (13%) | catalogued as COSV65670657; called by pindel, varscan2
- FUT8 | c.1033G>T p.E345* (on ENST00000360689 / NM_001371534.1; = p.E182* on NM_004480.4) | Nonsense Mutation (SNP) | VAF 35/123 reads (28%) | catalogued as COSV61282406, COSV61286786; called by muse, mutect2, varscan2
- FXR1 | c.380T>C p.F127S | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV99976250; called by muse, mutect2, varscan2
- FXR2 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV51468605; called by muse, mutect2, varscan2
- FYB1 | c.1578G>T p.K526N | Missense Mutation (SNP) | VAF 78/387 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60943808, COSV60951390; called by muse, mutect2, varscan2
- FYCO1 | c.1529C>A p.S510Y | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV99945347; called by muse, mutect2
- GABPB1 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV99589652; called by muse, mutect2
- GABRA3 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 44/857 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.086); catalogued as rs868315790, COSV100942422; called by muse, mutect2
- GABRB3 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as rs766672883, COSV100158514, COSV54670778; called by muse, mutect2, varscan2
- GABRP | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 33/184 reads (18%) | catalogued as COSV54663737; called by muse, mutect2, varscan2
- GABRP | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 9/164 reads (5%) | catalogued as COSV99516644; called by muse, mutect2
- GABRQ | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1357029655, COSV100941144; called by muse, mutect2
- GADL1 | c.1110C>A p.F370L | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.854); catalogued as COSV56982334; called by muse, mutect2
- GALNT1 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 16/222 reads (7%) | catalogued as COSV99321951; called by muse, mutect2
- GALNT2 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 11/151 reads (7%) | catalogued as COSV100795554; called by muse, mutect2
- GALNTL5 | c.1182G>T p.Q394H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.501); catalogued as COSV67180466; called by muse, mutect2, varscan2
- GALNTL6 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV72491706; called by muse, mutect2, varscan2
- GAS2L2 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs139833672; called by muse, mutect2, varscan2
- GBP7 | c.1690T>G p.F564V | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV54010336; called by muse, mutect2, varscan2
- GCC1 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50001350; called by muse, mutect2, varscan2
- GCC1 | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV50001353; called by muse, mutect2, varscan2
- GCC2 | c.134A>C p.K45T | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59174873; called by muse, mutect2
- GCG | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100972727, COSV64961667, COSV99072052; called by muse, mutect2, varscan2
- GDF9 | c.1039C>A p.L347I | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.426); catalogued as COSV51526662; called by muse, mutect2, varscan2
- GEN1 | c.1833A>C p.K611N | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.265); catalogued as COSV58057262; called by muse, mutect2, varscan2
- GFM2 | c.63+2T>C p.X21_splice | Splice Site (SNP) | VAF 13/97 reads (13%) | catalogued as COSV99713617; called by muse, mutect2, varscan2
2,007 further variants in this file (1,530 protein-altering or splice-affecting, 413 silent, 64 other) are not listed here.
